Somatic mutation profile of tumor specimen BA2834D (aliquot aq-BA2834D) from BEATAML1.0 case 2023, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with inv(3)(q21q26.2) or t(3;3)(q21;q26.2), RPN1-EVI1; Tissue or organ of origin: Bone marrow; Age at diagnosis: 71.0 years (25,951 days).
Specimen BA2834D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c33b5b2d-8089-4623-96b5-39ee5e966776.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2848D (Solid Tissue Normal), aliquot aq-BA2848D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c18502e0-e1bc-4b6e-9494-e2fca7c1449e

The open-access MAF lists 9 somatic variants for this specimen: 8 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, 3'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLNB | c.6596G>C p.G2199A | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.965); catalogued as COSV55882736; called by mutect2, varscan2
- PGAM4 | c.349C>T p.R117C | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.107); catalogued as rs1569549338; called by mutect2, varscan2
- SH3PXD2A | c.1093G>A p.E365K (on ENST00000369774 / NM_001365079.1; = p.E337K on NM_014631.2) | Missense Mutation (SNP) | VAF 60/160 reads (38%) | SIFT tolerated (0.32); PolyPhen benign (0.018); catalogued as rs141288204; called by muse, mutect2, varscan2
- SQLE | c.1339A>G p.I447V | Missense Mutation (SNP) | VAF 40/123 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs376815713; called by muse, mutect2, varscan2
- SRCAP | c.6452G>A p.R2151H | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1247583725, COSV52667363; called by muse, mutect2, varscan2
- CIB1 | c.51+6C>T | Splice Region (SNP) | VAF 9/23 reads (39%) | called by muse, mutect2, varscan2
- PCDHA11 | c.2267G>A p.R756K | Missense Mutation (SNP) | VAF 39/102 reads (38%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SUMO2 | c.92A>C p.Q31P | Missense Mutation (SNP) | VAF 27/139 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.152); called by muse, mutect2, varscan2
- DLGAP3 | c.*145C>G | 3'UTR (SNP) | VAF 17/33 reads (52%) | catalogued as rs1254582031; called by muse, mutect2, varscan2
